Somatic mutation profile of tumor specimen TCGA-XM-A8RL-01A (aliquot TCGA-XM-A8RL-01A-11D-A423-09) from TCGA case TCGA-XM-A8RL, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B1, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 44.9 years (16,384 days).
Specimen TCGA-XM-A8RL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2728d19c-65fb-4661-b862-0c9869fa8642.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-A8RL-10A (Blood Derived Normal), aliquot TCGA-XM-A8RL-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29af7cf3-a234-43c6-9d11-e11e8c058345

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR1 | c.5323C>A p.H1775N | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- METTL26 | c.428C>A p.A143D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MRNIP | c.338A>G p.K113R | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- FMN2 | c.702G>A p.A234= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- RAB33A | c.327C>T p.N109= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99924472; called by muse, mutect2
